Somatic mutation profile of tumor specimen TARGET-20-PARCZL-04A (aliquot TARGET-20-PARCZL-04A-01D) from TARGET case TARGET-20-PARCZL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,806 days).
Specimen TARGET-20-PARCZL-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ba94a26-4b18-4e9b-b2f0-89184e600309.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCZL-14A (Bone Marrow Normal), aliquot TARGET-20-PARCZL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00d28b32-0dca-43be-8d91-6bed235fcbaf

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 51/177 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMC3 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62419567; called by muse, mutect2
- KMT2D | c.14268dup p.P4757Tfs*25 | Frame Shift Ins (INS) | VAF 36/143 reads (25%) | called by mutect2, pindel, varscan2
